Somatic mutation profile of tumor specimen TCGA-13-1488-01A (aliquot TCGA-13-1488-01A-01W-0549-09) from TCGA case TCGA-13-1488, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.5 years (21,726 days).
Specimen TCGA-13-1488-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67975836-171a-4642-8b0b-7dea41112eac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1488-10A (Blood Derived Normal), aliquot TCGA-13-1488-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3c817a6-44d1-441a-9cbf-4ebb9ee563d7

The open-access MAF lists 177 somatic variants for this specimen: 134 protein-altering or splice-affecting, 36 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 36, Nonsense Mutation 13, Splice Site 3, Splice Region 3, 3'UTR 2, Frame Shift Del 2, Intron 2, 3'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 168/202 reads (83%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1727A>G p.D576G | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV55934048; called by muse, mutect2, varscan2
- ADD3 | c.1740G>C p.E580D | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV53321597; called by muse, mutect2
- ADGRE3 | c.332A>C p.N111T | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV53729710; called by muse, mutect2, varscan2
- ADRA1A | c.768C>G p.H256Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV52361265, COSV52373781; called by muse, mutect2, varscan2
- ALLC | c.560G>T p.W187L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.18); catalogued as COSV99378217; called by muse, mutect2, varscan2
- ALLC | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99378221; called by muse, mutect2, varscan2
- AP002512.3 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV99688122; called by muse, mutect2
- AP1M2 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV51566617; called by muse, mutect2, varscan2
- ASPM | c.5714A>G p.Q1905R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99661024; called by muse, mutect2
- BATF | c.168G>C p.L56= | Splice Region (SNP) | VAF 15/33 reads (45%) | catalogued as COSV54375633; called by muse, mutect2, varscan2
- BMX | c.634A>C p.S212R | Missense Mutation (SNP) | VAF 285/559 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.307); catalogued as rs760301583, COSV59590987; called by muse, mutect2, varscan2
- BNC2 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101034309; called by muse, mutect2
- C3 | c.4022C>A p.T1341N | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55571258; called by muse, mutect2, varscan2
- C6 | c.1726A>C p.T576P | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54708345; called by muse, mutect2
- CARNS1 | c.1322T>G p.F441C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100322215; called by muse, mutect2
- CCNB3 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV52070655, COSV52072092; called by muse, mutect2, varscan2
- CD200R1L | c.404A>G p.H135R | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV68004054; called by muse, mutect2, varscan2
- CERCAM | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100863781, COSV65711988; called by muse, mutect2
- CES3 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57593156; called by muse, mutect2, varscan2
- CYFIP2 | c.2687C>G p.T896S (on ENST00000616178 / NM_001291722.2; = p.T871S on NM_014376.4) | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV56636382; called by muse, mutect2, varscan2
- DCAF16 | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.931); catalogued as COSV66384159; called by muse, mutect2, varscan2
- DEFB118 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 34/249 reads (14%) | catalogued as rs764034779, COSV53619565, COSV53620056; called by muse, mutect2, varscan2
- DEFB125 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 119/658 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as COSV66703199; called by muse, mutect2, varscan2
- DENND3 | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV52801954; called by muse, mutect2, varscan2
- DMD | c.10801C>T p.Q3601* | Nonsense Mutation (SNP) | VAF 6/136 reads (4%) | catalogued as CM098463; called by muse, mutect2
- DMRT3 | c.1146C>A p.S382R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV51903735; called by muse, mutect2, varscan2
- DNAH5 | c.13015A>T p.I4339F | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99453681; called by muse, mutect2
- DOC2A | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100451380; called by muse, mutect2
- DOCK2 | c.3073-1G>T p.X1025_splice | Splice Site (SNP) | VAF 75/267 reads (28%) | catalogued as COSV56952258; called by muse, mutect2, varscan2
- DOCK5 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV52399048; called by muse, mutect2, varscan2
- EFHC1 | c.690T>A p.D230E | Missense Mutation (SNP) | VAF 75/365 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as COSV64135977; called by muse, mutect2, varscan2
- FAM204A | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 74/308 reads (24%) | catalogued as COSV64988467; called by muse, mutect2, varscan2
- FAM71C | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100175666; called by muse, mutect2
- FAT3 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV53096451; called by muse, mutect2, varscan2
- FBXO38 | c.3379G>A p.D1127N (on ENST00000340253 / NM_205836.3; = p.D1052N on NM_030793.5) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs145662452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FEZF2 | c.1361C>G p.T454S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs770155183, COSV99334991; called by muse, mutect2, varscan2
- FRMPD1 | c.1429A>C p.S477R | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV100899623; called by muse, mutect2
- GAP43 | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100525925; called by muse, mutect2, varscan2
- GCNT4 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 117/221 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV59280699; called by muse, varscan2
- GPHN | c.1031T>A p.I344N (on ENST00000315266 / NM_001377519.1; = p.I377N on NM_020806.5) | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.172); catalogued as COSV59477335; called by muse, mutect2, varscan2
- GPR171 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99854509; called by muse, mutect2
- GPRC6A | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 32/391 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV100114735, COSV59953535; called by muse, mutect2
- H2BC9 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1489552386, COSV55099675; called by muse, mutect2, varscan2
- H4-16 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV63761996; called by muse, mutect2, varscan2
- HLA-DQA2 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 36/498 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100890788; called by muse, mutect2
- HROB | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs773745843, COSV99809383; called by muse, mutect2, varscan2
- HSPA5 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV52333918, COSV52334853; called by muse, mutect2, varscan2
- IL18R1 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99295467; called by muse, mutect2
- IMPA1 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 41/260 reads (16%) | catalogued as COSV99809102; called by muse, mutect2, varscan2
- ITGA4 | c.1468G>T p.G490* | Nonsense Mutation (SNP) | VAF 21/170 reads (12%) | catalogued as COSV51999250; called by muse, mutect2, varscan2
- ITIH4 | c.152C>A p.T51K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56573061, COSV56576209; called by muse, mutect2, varscan2
- ITLN1 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100406360; called by muse, mutect2, varscan2
- KBTBD4 | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.959); catalogued as COSV55454145; called by muse, mutect2
- KDM1A | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.987); catalogued as COSV100752683, COSV63087405; called by muse, mutect2, varscan2
- KDM4D | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100624354; called by muse, mutect2
- KIAA1217 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV56815120; called by muse, mutect2, varscan2
- KIF13A | c.3290G>C p.R1097T | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52447384; called by muse, mutect2, varscan2
- KIF4B | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs758725223, COSV70528770; called by muse, mutect2, varscan2
- KLHDC7A | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV68769416; called by muse, mutect2, varscan2
- LAMA4 | c.2055T>C p.S685= (on ENST00000230538 / NM_001105206.3; = p.S678= on NM_002290.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 20/262 reads (8%) | catalogued as COSV100039337; called by muse, mutect2
- LEPR | c.3269G>T p.S1090I | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs1016030357, COSV100848418; called by muse, mutect2
- LIPJ | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV64245213; called by muse, mutect2, varscan2
- LMAN1 | c.1478T>C p.I493T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV99195369; called by muse, mutect2, varscan2
- LRRK1 | c.5493C>G p.H1831Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.15); catalogued as COSV99442874; called by muse, mutect2, varscan2
- MCOLN2 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52294841; called by muse, mutect2, varscan2
- MRGPRX1 | c.833T>G p.F278C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV100246152; called by muse, mutect2
- MRPL42 | c.262C>G p.H88D | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV62355834; called by muse, mutect2, varscan2
- NAT2 | c.674T>C p.L225S | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54061751; called by muse, mutect2, varscan2
- NAV2 | c.6265G>C p.E2089Q (on ENST00000396087 / NM_001244963.2; = p.E2030Q on NM_145117.5) | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.464); catalogued as COSV60657593, COSV60658253; called by muse, mutect2, varscan2
- NCKAP5 | c.5495G>C p.C1832S | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.134); catalogued as COSV100494197; called by muse, mutect2
- NFRKB | c.3364G>C p.G1122R (on ENST00000446488 / NM_001143835.2; = p.G1147R on NM_006165.3) | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV58757313; called by muse, mutect2, varscan2
- NPFFR2 | c.1363T>C p.C455R | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV58148473; called by muse, mutect2, varscan2
- NUF2 | c.256A>C p.S86R | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV54843162; called by muse, mutect2, varscan2
- OSCP1 | c.1086C>G p.I362M (on ENST00000356637 / NM_001330493.1; = p.I352M on NM_145047.5) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV52485557; called by muse, mutect2, varscan2
- P2RY6 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.998); catalogued as rs1052603054, COSV62935608; called by muse, mutect2
- PALM2AKAP2 | c.386C>A p.S129Y (on ENST00000374531 / NM_001037293.2; = p.S127Y on NM_007203.5) | Missense Mutation (SNP) | VAF 239/545 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV57117829; called by muse, mutect2, varscan2
- PAPPA2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs548559188, COSV62787700; called by muse, mutect2
- PARP4 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67961319; called by muse, mutect2, varscan2
- PASK | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52150975; called by muse, mutect2, varscan2
- PCDHGC4 | c.233A>T p.D78V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52742252, COSV52748689; called by muse, mutect2, varscan2
- PCLO | c.2309C>A p.S770* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as COSV61626742; called by muse, mutect2, varscan2
- PCM1 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.535); catalogued as COSV100279538; called by muse, mutect2
- PDE10A | c.1418A>T p.E473V | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100605675; called by muse, mutect2
- PDZRN4 | c.1908G>T p.K636N (on ENST00000402685 / NM_001164595.2; = p.K378N on NM_013377.4) | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.559); catalogued as COSV54197642; called by muse, mutect2, varscan2
- PEG3 | c.4378G>A p.D1460N | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs1322922841, COSV55630095, COSV55640882; called by muse, mutect2, varscan2
- PIGO | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as rs974939782, COSV53053247; called by muse, mutect2, varscan2
- PIK3CA | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371836681, COSV99843110; called by muse, mutect2
- PLCB4 | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1244478803, COSV53793656; called by muse, mutect2, varscan2
- POTEF | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV62540644; called by muse, mutect2, varscan2
- PPP1R3B | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60099290; called by muse, mutect2, varscan2
- PSME4 | c.4520+2T>C p.X1507_splice | Splice Site (SNP) | VAF 14/267 reads (5%) | catalogued as COSV101122634; called by muse, mutect2
- RAB37 | c.615G>T p.Q205H (on ENST00000392613 / NM_001006638.3; = p.Q198H on NM_175738.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV52852882; called by muse, mutect2, varscan2
- RNASE2 | c.109T>C p.W37R | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58941046; called by muse, mutect2, varscan2
- RNASET2 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.284); catalogued as COSV99218657; called by muse, mutect2, varscan2
- RNF13 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100694269; called by muse, mutect2
- RNF149 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54863485; called by muse, mutect2, varscan2
- ROBO2 | c.2854+1G>A p.X952_splice | Splice Site (SNP) | VAF 18/205 reads (9%) | catalogued as COSV59905585; called by muse, mutect2
- RPS6KA5 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56220162, COSV56221203, COSV56221827; called by muse, mutect2, varscan2
- SCAF8 | c.1304C>G p.S435* | Nonsense Mutation (SNP) | VAF 18/356 reads (5%) | catalogued as COSV65790750; called by muse, mutect2
- SEC23A | c.1525C>G p.Q509E | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1398399095, COSV99075675; called by muse, mutect2
- SELE | c.749A>T p.N250I | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100325101; called by muse, mutect2
- SEPTIN1 | c.812C>G p.P271R (on ENST00000321367; = p.P224R on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100363084, COSV58441755; called by muse, mutect2, varscan2
- SLC23A1 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100812094; called by muse, mutect2, varscan2
- SLC6A12 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62884542; called by muse, mutect2, varscan2
- SNAP47 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 43/93 reads (46%) | catalogued as COSV59916704; called by muse, mutect2, varscan2
- SSH1 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58463995; called by muse, mutect2, varscan2
- SUPT6H | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV58926503; called by muse, mutect2, varscan2
- TBC1D8 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV65211373; called by muse, mutect2, varscan2
- TBCCD1 | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV100112134; called by muse, mutect2
- TCTEX1D2 | c.420C>G p.F140L | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV53057028; called by muse, mutect2, varscan2
- THEMIS | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64070244, COSV64070376; called by muse, mutect2, varscan2
- TNS1 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50697077; called by muse, mutect2, varscan2
- TRPC7 | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565522086, COSV61456456, COSV61462249; called by muse, mutect2, varscan2
- UGT2A3 | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV52359600; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99692099; called by muse, mutect2, varscan2
- USP4 | c.558A>C p.K186N | Missense Mutation (SNP) | VAF 75/112 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV55536119; called by muse, mutect2, varscan2
- USP40 | c.2153G>C p.R718T | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV52479457; called by muse, mutect2, varscan2
- VPS13B | c.2696C>A p.S899Y | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62138406; called by muse, mutect2, varscan2
- ZBED4 | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV53465031; called by muse, mutect2, varscan2
- ZFP91 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 14/251 reads (6%) | catalogued as COSV100284732; called by muse, mutect2
- ZIM2 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | catalogued as rs144796320, COSV99689256; called by muse, mutect2, varscan2
- ZNF619 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59029736; called by muse, mutect2, varscan2
- ZNF677 | c.1316C>A p.A439D | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV61719922, COSV61720340; called by muse, mutect2, varscan2
- ZNF800 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56174893; called by muse, mutect2
- ZZZ3 | c.2005A>G p.K669E | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as COSV66232169; called by muse, mutect2, varscan2
- CNST | c.1726C>T p.L576F | Missense Mutation (SNP) | VAF 16/620 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2
- COL15A1 | c.3192T>G p.A1064= | Splice Region (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- EXOC8 | c.1437_1438delinsT p.G480Afs*43 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by pindel, varscan2*
- FRG2C | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2
- MAP3K15 | c.3625_3626del p.L1209Rfs*33 | Frame Shift Del (DEL) | VAF 84/257 reads (33%) | called by pindel, varscan2
- MRC1 | c.3893G>C p.G1298A | Missense Mutation (SNP) | VAF 118/715 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF10 | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 23/263 reads (9%) | called by muse, mutect2, varscan2
- ZNF560 | c.1667G>T p.C556F | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.074); called by muse, mutect2
- CACHD1 | c.2133C>G p.V711= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as COSV51551537; called by muse, mutect2, varscan2
- CD3D | c.162C>T p.D54= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1224759102, COSV52674497; called by muse, mutect2, varscan2
- CLK2 | c.834C>G p.V278= (on ENST00000368361 / NM_001294339.2; = p.V277= on NM_003993.4) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100226910; called by muse, mutect2, varscan2
- CYP4F8 | c.876G>A p.K292= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100358229; called by muse, mutect2
- DMBX1 | c.873G>A p.P291= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs373688410, COSV100760675, COSV63602570; called by muse, mutect2, varscan2
- FAM71C | c.192C>T p.N64= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100175821; called by muse, mutect2
- GYS2 | c.858A>G p.K286= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as COSV99680211; called by muse, mutect2, varscan2
- ITPR1 | c.2227A>C p.R743= (on ENST00000354582; = p.R728= on NM_002222.7) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV56976579; called by muse, mutect2, varscan2
- KATNAL2 | c.609A>G p.E203= (on ENST00000356157 / NM_001353899.1; = p.E131= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/190 reads (29%) | catalogued as COSV55296937; called by muse, mutect2, varscan2
- KIAA1755 | c.885C>T p.G295= | Silent (SNP) | VAF 83/292 reads (28%) | catalogued as rs982753326, COSV54074655, COSV54075351; called by muse, mutect2, varscan2
- KIF26B | c.1245C>T p.L415= | Silent (SNP) | VAF 111/462 reads (24%) | catalogued as COSV63639685; called by muse, mutect2, varscan2
- KIFBP | c.1860G>A p.L620= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV62831234; called by muse, mutect2, varscan2
- LARS2 | c.942C>T p.I314= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV55526682; called by muse, mutect2, varscan2
- LRRC8D | c.1428G>C p.L476= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV61578486; called by muse, mutect2
- MFSD14B | c.327G>A p.R109= | Silent (SNP) | VAF 51/261 reads (20%) | catalogued as rs765441525, COSV64700627; called by muse, mutect2, varscan2
- MYH6 | c.4638G>C p.L1546= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV62448581, COSV62449351; called by muse, mutect2, varscan2
- NRK | c.324C>T p.S108= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV54593254, COSV54607013; called by muse, mutect2, varscan2
- OR8B2 | c.72G>T p.R24= | Silent (SNP) | VAF 44/570 reads (8%) | catalogued as COSV100899496, COSV66665742; called by muse, mutect2
- PCLO | c.1704G>A p.Q568= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV61626753; called by muse, mutect2, varscan2
- PI4K2B | c.1023T>G p.A341= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99335630; called by muse, mutect2, varscan2
- PNMA1 | c.630C>T p.A210= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs1430451522, COSV54094020; called by muse, mutect2, varscan2
- PNMT | c.567A>T p.P189= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV54092738, COSV54093548; called by muse, mutect2, varscan2
- POLR1C | c.48G>C p.L16= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100397111; called by muse, varscan2
- PSG6 | c.711G>A p.K237= | Silent (SNP) | VAF 71/262 reads (27%) | catalogued as COSV51833674, COSV99414492; called by muse, mutect2, varscan2
- PSORS1C2 | c.372G>A p.E124= | Silent (SNP) | VAF 4/61 reads (7%) | catalogued as rs1441059802, COSV99456303; called by muse, mutect2
- S100P | c.66G>A p.E22= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99588585; called by muse, mutect2, varscan2
- SECISBP2 | c.768A>G p.R256= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV60528155; called by muse, mutect2, varscan2
- SH3BGRL | c.99A>G p.G33= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as COSV64620419, COSV64620568; called by muse, mutect2, varscan2
- SPEF2 | c.4779A>G p.P1593= | Silent (SNP) | VAF 17/579 reads (3%) | catalogued as COSV100289376; called by muse, mutect2
- SYK | c.754T>C p.L252= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV101002610; called by muse, mutect2
- TBCCD1 | c.1035C>G p.L345= | Silent (SNP) | VAF 24/399 reads (6%) | catalogued as rs141952801, COSV58664382; called by muse, mutect2
- TM9SF2 | c.1704C>T p.T568= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as rs1331836484, COSV100899768; called by muse, mutect2
- TSPAN6 | c.552T>G p.T184= | Silent (SNP) | VAF 67/113 reads (59%) | catalogued as COSV65957253; called by muse, mutect2, varscan2
- UGT3A2 | c.1419C>G p.P473= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99236804; called by muse, mutect2, varscan2
- USP19 | c.1278G>A p.E426= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV60045556; called by muse, mutect2, varscan2
- ZFHX4 | c.9000C>T p.G3000= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs1183735569, COSV50565031; called by muse, mutect2, varscan2
- EPB41L4A | chr5:112161492 G>C | 3'Flank (SNP) | VAF 17/106 reads (16%) | catalogued as rs756510184; called by muse, mutect2, varscan2
- GLYATL1 | c.-52A>C | 5'UTR (SNP) | VAF 13/101 reads (13%) | catalogued as COSV55608267; called by muse, mutect2, varscan2
- NFAT5 | c.73+2163G>A | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV63026405; called by muse, mutect2, varscan2
- RIMKLA | c.*2T>C | 3'UTR (SNP) | VAF 31/214 reads (14%) | catalogued as COSV101290577; called by muse, mutect2, varscan2
- RRP7A | c.*3852C>T | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, varscan2
- SNORD116-6 | n.38del | RNA (DEL) | VAF 112/205 reads (55%) | called by mutect2, pindel, varscan2
- TTN | c.34265-460G>A | Intron (SNP) | VAF 7/34 reads (21%) | called by mutect2, varscan2
